Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GP, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GP-01A (Primary Tumor).

[page 1 of 2]
GROSS:

Specimen state: Fresh

Operation: Distal gastrectomy

Measurement: Greater curvature 23.8 cm

Lesser curvature 13.7 cm

Proximal resection margin 19.7 cm

Distal resection margin 6.0 cm

Duodenum 0.7 cm

Lesion: Ulceroinfiltrative mass

Tumor size: 4.8 x 3.6 x 1.1 cm

Location: Lesser curvature side of distal antrum

Tumor type: AGC (Borrmann type III)

From proximal resection margin - 9.3 cm

From distal resection margin - 1.0 cm

Gross serosal invasion: No

Blocks

T1-4 and TB, tumor and surrounding tissue x 5

A, antrum mucosa x 1

B and NB, body mucosa x 2

P, proximal resection margin x 1

D and DRM, distal resection margin x 2

LN1-2, superior gastric lymph nodes x 2

LN3-4, inferior gastric lymph nodes x 2

LN5, '1' lymph nodes x 1

LN6, '4sb' lymph nodes x 1

LN7, '5' lymph nodes x 1

LN8, '6' lymph nodes x 1

LN9, '7' lymph nodes x 1

LN10-11, '8' lymph nodes x 2

LN12, '9' lymph nodes x 1

LN13-14, '11p' lymph nodes x 2

LN15, '12' lymph nodes x 1

ICD-0-3

adenocarcinoma, diffuse type 8145/3

Site: stomach, antrum C16.3

lw
9/27/12

MICROSCOPIC:

Tumor type: Adenocarcinoma

Differentiation: Moderately differentiated

Depth of tumor invasion:

[page 2 of 2]
T2: Tumor invades muscularis propria
Margins: Proximal resection margin (-)
Distal resection margin (-)
Ming classification (Growth pattern): Infiltrative
Lymphoid reaction: Absent
Lymphovascular invasion: Present
Venous (large vessel) invasion: Absent
Perineural invasion: Absent
Lymph node metastasis: Present (2/63)
Pathologic stage: pT2N1Mx (AJCC 7th edition)

DIAGNOSIS:

Stomach, distal gastrectomy:
Adenocarcinoma, moderately differentiated, infiltrating
(advanced gastric cancer)

<Addendum>

Final diagnosis: Stomach Adenocarcinoma, Diffuse Type *per clarification by the TSS.*

Lymph node, perigastric, distal gastrectomy:
Superior gastric: No tumor present (0/10)
Inferior gastric: No tumor present (0/7)

Lymph node, regional, biopsy:
Labeled as '1': No tumor present (0/6)
Labeled as '4sb': No tumor present (0/2)
Labeled as '5': No tumor present (0/1)
Labeled as '6': Metastatic carcinoma, primary in stomach (1/6)
Labeled as '7': No tumor present (0/4)
Labeled as '8': No tumor present (0/4)
Labeled as '9': No tumor present (0/9)
Labeled as '11p': No tumor present (0/6)
Labeled as '12': Metastatic carcinoma, primary in stomach (1/8)

Source: NCI Genomic Data Commons file 66ed6ea8-8090-49fb-af09-7eb6722ddc81 (TCGA-HU-A4GP.1C853211-B7DB-458E-9F91-0B1FBD914BCA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).